Surgical pathology report (de-identified scan), TCGA case TCGA-WE-A8K6, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Norfolk and Norwich Hospital, specimen TCGA-WE-A8K6-06A (Metastatic).

[page 1 of 4]
Sample (Tissue) Collected Received

Surgical Histology

HISTOPATHOLOGY REPORT

LAB No:

CASE HISTORY

Right axillary nodes - previous history of melanoma ?Metastatic to lymph node.

MACROSCOPIC

These are two cores of tissue each 10 mm in length.

MICROSCOPY:

We received 1x H+E slide and 6 immunohistochemistry slides from labelled " , Lx3, S100, MELA, CK7, CK20, CK5/6 and PSA" for discussion at the

Core biopsy showing aggregates of atypical naevoid cells (S100 positive) which are mitotically active and which show focal necrosis, in keeping with metastatic malignant melanoma.

DIAGNOSIS:

RIGHT AXILLARY LYMPH NODE BIOPSY: METASTATIC MALIGNANT MELANOMA.

REPORTED BY:

, Consultant Histopathologist.

REPORT DATE:

Sample (Tissue) Collected Received

Surgical Histology

Surgical Histology

Report to Cancer Registry

HISTOPATHOLOGY REPORT

**SUPPLEMENTARY REPORT

**

LAB No:

1CD-0-3

Melanoma, malignant, NOS 8720/3
Site: Axillary lymph node c77.4

/w 7/18/14

CASE HISTORY:

Metastatic melanoma. Specimen has been tissue banked. Has splenomegaly therefore ?non-Hodgkin lymphoma

MACROSCOPIC:

Fat and attached muscle 15 x 8 x 4 cm which has been inked and incised at one point (A = node nearest suture). At the incision site is an involved lymph node 3 cm diameter which is at least 0.5 cm from the closest margin (B).

[page 2 of 4]
MICROSCOPY:

Metastatic malignant melanoma is present in one lymph node, 3 cm diameter (macroscopic measurement). The capsule of the node is fibrotic but there is no definite extracapsular spread. 16 other lymph nodes are negative for tumour. There is no evidence of lymphoma

DIAGNOSIS:

RIGHT AXILLARY DISSECTION: METASTATIC MALIGNANT MELANOMA

REPORTED BY:

Consultant Histopathologist

REPORT DATE:

Supplementary report,

BRAF immunohistochemistry

SUPPLEMENTARY REPORT

The case is sent to testing.

for BRAF

Real-time PCR of the BRAF gene has revealed the presence of a mutation at codon 600 of the BRAF gene.

technique does not differentiate between V600E and V600K.

MELANOMA: PATHOGENIC MUTATION WITHIN CODON 600 OF BRAF.

Sample

(Miscellaneous) Collected

Received

CASE HISTORY:

Metastatic melanoma. New nodule.

MACROSCOPIC:

3 air dried slides dated

Error logged: Insufficient identifiers

MICROSCOPY:

Numerous, dyscohesive epithelioid cells with markedly pleomorphic, atypical nuclei, a few of which contain pseudoinclusions. Appearances are

[page 3 of 4]
of malignant cells entirely in keeping with metastatic melanoma.

DIAGNOSIS:

RIGHT AXILLARY FNA: METASTATIC MELANOMA

REPORTED BY:

Dr. , Consultant Histopathologist.

REPORT DATE:

Radiology Examination

CT HEAD CT Scan

CT HEAD CT Scan

CT HEAD CT Scan

Clinical Information:

metastatic melanoma right axilla. Recurrence in axilla scar - rapidly growing
? stage IV

metastatic melanoma right axilla. Recurrence in axilla scar - rapidly growing
? stage IV

Report:

Comparison is made to the previous CT from

There is a 7 mm enhancing lesion seen within the medial right fronto parietal cortex (series 4, image 22; series 6, image 45). This was not present previously, and is suspicious for a metastasis. No other focal parenchymal lesion.

There is no supraclavicular, left axillary, hilar or mediastinal adenopathy. There is a 43 x 78 mm mass within the right axilla at the site of previous surgery. This has increased in size from 28 x 70 mm previously. There is peripheral reticular shadowing seen within the lungs in keeping with fibrosis. There are pleural plaques suggesting this is related to previous asbestos exposure. No destructive bone lesion.

There is a new 16 mm low-density lesion in segment 4 of the liver (image 45). A smaller 10 mm lesion is seen within segment 6 (image 58). These are in keeping with metastases. The spleen is enlarged measuring 19 cm unchanged from previously. There are splenic hilar varices and left gastric varices unchanged from previously.

The pancreas, adrenals and kidneys appear normal. There are

[page 4 of 4]
non-enlarged upper abdominal nodes unchanged from previously. No abdominal, pelvic or inguinal adenopathy. No large stenosing lesion evident in the unopacified large bowel. There are no skin or subcutaneous nodules.

Conclusion: Progressive disease with enlargement of the right axillary mass with new cerebral and liver metastases in keeping with stage IV disease.

New copy w/o PHI - originally
Signed 11/6/13.

Source: NCI Genomic Data Commons file b121bc11-44ae-49ca-acf4-b5eec7138630 (TCGA-WE-A8K6.D8730383-F277-40B1-A7F0-D230E4BCD836.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).